Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5516, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5516-01A (Primary Tumor).

PATIENT HISTORY:

PSA of 10.9 Left mid has Gleason of 4 + 3. The left apex Gleason of 3 + 4. Right mid Gleason of 4 + 4. The right apex Gleason of 3 + 3.

PRE-OP DIAGNOSIS: Prostate cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Prostatectomy.

FINAL DIAGNOSIS:**PART 1:**

LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN 3 LYMPH NODES.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN 3 LYMPH NODES.

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3+4=7 WITH TERTIARY PATTERN 5.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.4 cm.
- C. THE CARCINOMA INVOLVES 15% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS 2 FOCI OF EXTRACAPSULAR EXTENSION IN THE LEFT POSTERIOR BASE (SLIDES 3C AND 3Y, 0.3 CM).
- E. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT3a N0 MX.
- K. TNM HISTOLOGIC GRADE = G3-4.
- L. BENIGN PROSTATIC HYPERPLASIA AND CHRONIC INFLAMMATION ARE NOTED.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 10.9
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	30%
WEIGHT OF PROSTATE:	50.38gm
TUMOR SIZE:	Maximum dimension: 1.4 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Multifocal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	6
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

TCGA - EJ - 5516

Source: NCI Genomic Data Commons file f2af8cf7-8864-463c-a174-4ea76c6aa659 (TCGA-EJ-5516.B15C052E-04F9-49D7-BCA9-DDDF59A7E9DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).